Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8188, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8188-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code:

Patient Age/Sex

SPECIMEN SUBMITTED:

Part A: ANTERIOR LEFT TEMPORAL LOBE

Part B: ANTERIOR LEFT TEMPORAL LOBE TUMOR

Final Diagnosis:

Left anterior temporal lobe, excisional biopsy (A, B) - Low grade oligoastrocytoma (WHO grade II).
- See comment.

Diagnosis Comment:

The neoplasm is of low cellularity with occasional foci of moderate cellularity. A subpopulation of nuclei throughout the neoplasm show increased pleomorphism. The oligodendroglioma phenotype is well-represented in all slides of specimen B, where the majority of the cells infiltrating the subcortical white matter show round nuclei and perinuclear halos. Cells with perinuclear halos are less common in specimen A. It is possible that the difference between specimens could be due in part to delayed fixation of specimen B. Mitotic figures are inconspicuous and very rare. Ki-67 labeling index is 1% in areas of low cellularity and 4.5% in the more cellular area in block A4. No vascular proliferation or necrosis is seen. Between 25 and 50% of nuclei label with antibodies to p53. The neoplastic cells label with antibodies to IDH1 (R132H).

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Resection.

Specimen handling: Frozen section and permanent section.

Site: Temporal lobe.

Laterality: Left

Diagnosis: Low grade oligoastrocytoma

WHO Grade: II

Ancillary test(s) ordered: Immunohistochemistry for Ki-67, p53, and IDH-1 (R132H), FISH for 1p, 19q, and EGFR. All performed on block A4. The FISH will be reported in an addendum.

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Des Plaines, IL). The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the Pathology and Laboratory Medicine Institute. The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR NOT AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block A4

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-q11.1) (CEP7) locus specific directly labeled probes

The following FISH results were obtained:

EGFR 3.2

CEP7 2.5

EGFR/CEP7 ratio 1.3

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [REDACTED] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma

Clinical Diagnosis:

BRAIN TUMOR

Gross Description:

A. Received fresh for frozen section diagnosis labeled "anterior left temporal lobe" is an irregular segment of brain tissue measuring 5.0 x 4.0 x 1.5 cm. Sectioning reveals a firm tan-white cut surface. No necrosis or softening is identified. The gray-white junction is blurred. A representative section is submitted for frozen section diagnosis in cassette A1 and kept frozen. Additional representative sections are submitted as follows: A2-A5 mass, A6 normal appearing brain tissue.

B. Received in formalin labeled "anterior left temporal lobe tumor" are three segments of tan-white brain tissue aggregating to 3.5 x 2.1 x 0.7 cm. The specimen is uniformly soft on palpation. Sectioning reveals gray-white homogenous cut surfaces. No necrosis or softening is identified. Totally submitted in formalin in cassettes B1-B3.

Microscopic:

{Not Entered}

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code:

Patient Age/Sex

SPECIMEN SUBMITTED:

Part A: ANTERIOR LEFT TEMPORAL LOBE

Part B: ANTERIOR LEFT TEMPORAL LOBE TUMOR

Final Diagnosis

Left anterior temporal lobe, excisional biopsy (A, B) - Low grade oligoastrocytoma (WHO grade II).
- See comment.

Diagnosis Comment:

The neoplasm is of low cellularity with occasional foci of moderate cellularity. A subpopulation of nuclei throughout the neoplasm show increased pleomorphism. The oligodendroglioma phenotype is well-represented in all slides of specimen B, where the majority of the cells infiltrating the subcortical white matter show round nuclei and perinuclear halos. Cells with perinuclear halos are less common in specimen A. It is possible that the difference between specimens could be due in part to delayed fixation of specimen B. Mitotic figures are inconspicuous and very rare. Ki-67 labeling index is 1% in areas of low cellularity and 4.5% in the more cellular area in block A4. No vascular proliferation or necrosis is seen. Between 25 and 50% of nuclei label with antibodies to p53. The neoplastic cells label with antibodies to IDH1 (R132H).

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Resection.

Specimen handling: Frozen section and permanent section.

Site: Temporal lobe.

Laterality: Left

Diagnosis: Low grade oligoastrocytoma

WHO Grade: II

Ancillary test(s) ordered: Immunohistochemistry for Ki-67, p53, and IDH-1 (R132H), FISH for 1p, 19q, and EGFR. All performed on block A4. The FISH will be reported in an addendum.

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

[REDACTED] The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [REDACTED] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR NOT AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block A4

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-q11.1) (CEP7) locus specific directly labeled probes [REDACTED]

The following FISH results were obtained:

EGFR 3.2

CEP7 2.5

EGFR/CEP7 ratio 1.3

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas [REDACTED]

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [REDACTED] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma

Clinical Diagnosis:

BRAIN TUMOR

Gross Description:

A. Received fresh for frozen section diagnosis labeled "anterior left temporal lobe" is an irregular segment of brain tissue measuring 5.0 x 4.0 x 1.5 cm. Sectioning reveals a firm tan-white cut surface. No necrosis or softening is identified. The gray-white junction is blurred. A representative section is submitted for frozen section diagnosis in cassette A1 and kept frozen. Additional representative sections are submitted as follows: A2-A5 mass, A6 normal appearing brain tissue.

B. Received in formalin labeled "anterior left temporal lobe tumor" are three segments of tan-white brain tissue aggregating to 3.5 x 2.1 x 0.7 cm. The specimen is uniformly soft on palpation. Sectioning reveals gray-white homogenous cut surfaces. No necrosis or softening is identified. Totally submitted in formalin in cassettes B1-B3.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 4720e2fc-bec3-4fd1-9044-f5dce0189fd9 (TCGA-FG-8188.7F0C279E-AECB-4BB2-925B-53A3B9BD866D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).